Gene-level copy-number profile of tumor specimen TARGET-40-0A4I3S-01A from TARGET case TARGET-40-0A4I3S, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 22.8 years (8,313 days).
Specimen TARGET-40-0A4I3S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.fff431af-69ad-5294-b478-69c2c2fc5650.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I3S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate.
https://portal.gdc.cancer.gov/files/c9e53b21-f709-41f4-b76d-cfb5aaf296eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 685; copy number 1: 2,506; copy number 2: 18,989; copy number 3: 5,346; copy number 4: 28,770; copy number 5: 1,800; copy number 6: 1,114; copy number 7: 339; copy number 8: 550; copy number 9: 71; copy number 10: 8; copy number 11: 30; copy number 13: 6; copy number 14: 9; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): 171 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–1,730,474, 18 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr17:19,495,385–22,706,703, 149 genes (broad region; genes not listed).
- chr17:52,985,513–52,987,652, 1 gene: LINC02876.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 115 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:61,816,419–61,816,522, 1 gene, copy number 9: RNU6-414P.
- chr2:7,141,227–7,899,725, 11 genes, copy number 9: RN7SKP112, AC010904.2, AC010904.1, AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1.
- chr2:13,000,953–14,992,066, 10 genes, copy number 11–14 (within-gene range 8–14): AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1.
- chr3:11,488,300–11,529,755, 2 genes, copy number 9: AC026185.1, AC022001.1.
- chr3:11,607,184–11,612,197, 2 genes, copy number 9: AC022001.2, AC022001.3.
- chr8:129,241,228–129,291,275, 3 genes, copy number 13: AC103833.2, AC103833.1, RN7SKP206.
- chr11:105,137,714–105,531,697, 1 gene, copy number 13 (within-gene range 2–13): CARD18.
- chr11:105,352,670–105,982,092, 4 genes, copy number 13–20 (within-gene range 6–20): Metazoa_SRP, GRIA4, HSPD1P13, RNU4-55P.
- chr12:121,096,027–121,430,623, 11 genes, copy number 11 (within-gene range 7–11): AC079602.3, SNORA70, AC079602.1, P2RX7, AC069209.2, AC069209.1, P2RX4, CAMKK2, ANAPC5, AC048337.1, RNF34.
- chr12:122,167,738–122,203,471, 1 gene, copy number 11 (within-gene range 7–11): LRRC43.
- chr12:122,203,681–122,422,632, 8 genes, copy number 11 (within-gene range 6–11): B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A, CLIP1, RPL21P1, CLIP1-AS1.
- chr12:125,808,668–125,983,665, 5 genes, copy number 10 (within-gene range 7–10): AC005252.2, AC005252.4, AC005252.3, AC005252.1, LINC00939.
- chr12:131,596,857–131,668,246, 9 genes, copy number 11: AC140063.1, AC117500.5, AC117500.3, LINC02414, AC117500.6, AC117500.4, RNA5SP377, AC117500.1, RPS6P21.
- chr18:24,725,762–24,986,980, 1 gene, copy number 9 (within-gene range 6–9): AC018697.1.
- chr18:45,983,536–46,266,992, 8 genes, copy number 9: PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25.
- chr18:48,475,487–48,479,228, 3 genes, copy number 10: RNA5SP456, AC024288.1, POLR3GP2.
- chr18:48,919,853–49,461,347, 8 genes, copy number 9 (within-gene range 2–9): SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1.
- chr18:65,917,782–68,528,123, 25 genes, copy number 9: AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P.
- chr18:71,665,148–71,788,128, 2 genes, copy number 9 (within-gene range 7–9): AC090312.2, LINC01899.

Autosomal genes at a single copy (total copy number 1): 866. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
